TCGA case TCGA-16-0861 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Toronto Western Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8a83ea25-d02e-4af8-9167-b29d3ef393cc

Demographics
Sex at birth: male; Race: white; Age at index: 65 years.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 65.1 years (23,778 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 47 days; Treatment dose: 4,000 cGy; Number of fractions: 15; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 65.4 years (23,872 days); Days to diagnosis: 94 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 94 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 94 days.
- Follow-up contact recording only the day: day 131.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-16-0861-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-16-0861-01A-01-TS2: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-16-0861-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent necrosis: 10; Percent stromal cells: 5.
- Sample TCGA-16-0861-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 131 days; disease-specific survival: event status not recorded, 131 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 94 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-16-0861-01A-01D-0384-01): tumor purity 0.88, ploidy 1.91, whole-genome doublings 0.
